Surgical pathology report (de-identified scan), TCGA case TCGA-WE-A8ZQ, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Norfolk and Norwich Hospital, specimen TCGA-WE-A8ZQ-06A (Metastatic).

[page 1 of 3]
Surgical Histology

Surgical Histology

ADDRESS FOR REPORT: PLASTIC SURGERY

HISTOPATHOLOGY REPORT

LAB No:

CASE HISTORY:

1.4 mm thick melanoma excised at Metastatic melanoma?
Residual disease? Slow growing lesion right thigh

MACROSCOPIC:

1. Melanoma left lower leg: ellipse of skin 5x3.4cm with underlying tissue to a depth of 0.7cm. There is a central linear scar up to 2.3cm. Cut surface appears unremarkable.
2. Lesion right thigh: skin ellipse 1.2x0.5cm with underlying tissue to a depth of 0.5cms. There is a central pigmented papule 0.4cms.
3. Sentinel lymph left groin, piece of fat 2.7x2.4x1cms containing a lymph node with a blue tinge up to 1.5cms.
4. Sentinel node number 2, left groin: piece of fat 2.6x1.5x0.8cms containing a lymph node up to 1cms.

MICROSCOPY:

1. Skin containing a healing wound. No residual melanoma seen
2. A compound naevus which appears completely excised
- 3, 4. No metastatic tumour seen in the sentinel lymph nodes

DIAGNOSIS:

SKIN, LEFT LOWER LEG AND LEFT GROIN SENTINEL LYMPH NODES: NEGATIVE FOR TUMOUR
SKIN, RIGHT THIGH: COMPOUND NAEVUS

REPORTED BY:

Consultant Histopathologist

REPORT DATE:

ICD-O-3

Melanoma, nodular 8721/3
Site: Lymph node, groin C77.4
JW 5/19/14

Sample

(Tissue) Collected

Received

Surgical Histology

Surgical Histology

ADDRESS FOR REPORT:

Copy To: , Consultant Histopathologist,

[page 2 of 3]
LAB No:

SPECIMEN OF:

CLINICAL DETAILS:

SPECIMEN OF:

CLINICAL DETAILS:

excision only, per TSS.

A pale ellipse of skin 44 x 15 x 8mm with a mottled dark brown domed central lesion 9mm diameter 3mm in height. Suture marks one edge 12 o'clock. 12 o'clock margin red inked, deep and other margin blue. Serial transverse sections starting from 9 o'clock in A. 3 in A, 2 in B, 3 in C

5 fragments labelled 'left groin' measuring between 2 - 5mm.
[5 in A]

Three slides received from [redacted] labelled
1A Thin, Melan A and S100.

I agree with the diagnosis of a malignant melanoma.

6 mm

[page 3 of 3]
Stage:pT3b

I agree with the diagnosis of metastatic malignant melanoma,
confirmed by S-100 immunostain and patchy Melan-A positivity.

DIAGNOSIS:

-SKIN, LEFT LEG: NODULAR MALIGNANT MELANOMA

-LEFT GROIN LYMPH NODE: METASTATIC MALIGNANT MELANOMA ✓

REPORTED BY:

, Consultant Histopathologist.

REPORT DATE:

Source: NCI Genomic Data Commons file 15843de0-ac7a-4c80-97b0-0bd3d32d83b4 (TCGA-WE-A8ZQ.E5763CB1-3912-44EF-855B-B6363E31E74F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).